Somatic mutation profile of tumor specimen TARGET-20-PARNJC-09A (aliquot TARGET-20-PARNJC-09A-01D) from TARGET case TARGET-20-PARNJC, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.9 years (3,609 days).
Specimen TARGET-20-PARNJC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1c0767c-fbaf-4215-96dc-72ccb3c1b5dc.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARNJC-14A (Bone Marrow Normal), aliquot TARGET-20-PARNJC-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cfc94b70-c882-4ff6-bb01-1c71c2683ed5

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Splice Site 1, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>C p.Q61P | Missense Mutation (SNP) | VAF 11/120 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- RAD21 | c.1705-2A>T p.X569_splice | Splice Site (SNP) | VAF 17/66 reads (26%) | catalogued as COSV52062532; called by muse, mutect2, varscan2
- TJP3 | c.1990G>A p.V664M | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372340881; called by mutect2, varscan2
- NCOR1 | c.272_273dup p.F92Rfs*39 | Frame Shift Ins (INS) | VAF 3/30 reads (10%) | called by mutect2, pindel
- AHNAK2 | c.6690C>T p.V2230= | Silent (SNP) | VAF 30/215 reads (14%) | catalogued as rs118166451; called by muse, mutect2, varscan2
